Gene-level copy-number profile of tumor specimen TCGA-34-2596-01A from TCGA case TCGA-34-2596, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 70.0 years (25,574 days).
Specimen TCGA-34-2596-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.b819adca-9b50-4270-92fd-34c2cc0c10fb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-34-2596-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7b695b80-51be-4e5e-9dd2-d8cd6f13ba6d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 8; copy number 2: 82; copy number 3: 26,417; copy number 4: 4,785; copy number 5: 4,526; copy number 6: 20,015; copy number 7: 470; copy number 8: 499; copy number 9: 1,225; copy number 10: 40; copy number 11: 460; copy number 12: 1,158; copy number 14: 54; copy number 16: 67.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-34-2596-01A-01D-0844-01): tumor purity 0.65, ploidy 1.57, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:80,109,262–80,247,514, 5 genes: ADNP2, PARD6G-AS1, PARD6G, AC139100.2, AC139100.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,958 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,959,287–89,117,844, 893 genes, copy number 9 (broad region; genes not listed).
- chr2:98,331,389–99,490,035, 26 genes, copy number 8: AC092675.1, CNGA3, AC092675.2, INPP4A, COA5, UNC50, MGAT4A, YWHAQP5, LINC02611, RNU4-84P, CRACDL, RNU7-46P, TSGA10, SMC3P1, AC079447.1, C2orf15, LIPT1, AC092587.1, MITD1, MRPL30, LYG2, LYG1, TXNDC9, EIF5B, REV1, AC018690.1.
- chr3:93,843,764–198,222,513, 1,800 genes, copy number 9–16 (broad region; genes not listed).
- chr4:49,096–7,112,399, 196 genes, copy number 8 (broad region; genes not listed).
- chr4:7,310,450–7,310,524, 1 gene, copy number 8: MIR4798.
- chr4:41,359,607–63,529,761, 279 genes, copy number 8–11 (broad region; genes not listed).
- chr5:7,226,156–16,617,058, 148 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr7:23,105,758–23,275,108, 6 genes, copy number 10 (within-gene range 6–10): KLHL7, AK3P3, NUP42, AC005082.2, AC005082.1, GPNMB.
- chr7:50,866,747–65,401,136, 320 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr7:129,055,223–133,170,514, 96 genes, copy number 9–11 (broad region; genes not listed).
- chr7:133,290,881–133,315,413, 2 genes, copy number 9: MIR6133, AC083875.1.
- chr7:137,164,043–141,888,092, 109 genes, copy number 7–14 (broad region; genes not listed).
- chr7:144,048,948–145,584,817, 34 genes, copy number 9 (within-gene range 4–9): OR2A5, OR2A25, OR2A41P, OR2A12, OR2A2, OR2A15P, OR2A14, OR2A13P, OR2A3P, OR2AO1P, CTAGE4, ARHGEF35, ARHGEF35-AS1, OR2A42, OR2A20P, AC074386.1, OR2A7, CTAGE8, ARHGEF34P, OR2A9P, OR2A1-AS1, OR2A1, ARHGEF5, NOBOX, PPIAP83, RNU6ATAC40P, TPK1, EEF1A1P10, RN7SKP174, EI24P4, AC073310.1, RPL7P59, AC004911.1, DPY19L4P2.
- chr7:147,146,342–147,167,572, 2 genes, copy number 9: DUTP3, RANP2.
- chr7:148,637,179–148,801,110, 4 genes, copy number 8: AC005229.1, AC005229.3, AC005229.4, CUL1.
- chr7:151,466,012–152,019,929, 9 genes, copy number 8 (within-gene range 4–8): RHEB, ETF1P2, PRKAG2, AC093583.1, PRKAG2-AS1, RNU6-604P, Y_RNA, AC074257.1, GALNTL5.
- chr7:152,759,749–152,936,981, 2 genes, copy number 8 (within-gene range 4–8): ACTR3B, AC006348.1.
- chr11:47,214,465–47,239,217, 1 gene, copy number 9 (within-gene range 3–9): DDB2.
- chr11:47,239,302–47,848,555, 30 genes, copy number 9 (within-gene range 6–9): ACP2, NR1H3, MADD, MADD-AS1, AC090582.1, MYBPC3, SPI1, AC090559.1, MIR4487, SLC39A13, PSMC3, RAPSN, CELF1, AC090559.2, RN7SL652P, NDUFS3, PTPMT1, KBTBD4, RNU5E-10P, KF459542.1, FAM180B, C1QTNF4, MTCH2, AGBL2, FNBP4, Y_RNA, NUP160, AC021443.1, RNA5SP340, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
